Somatic mutation profile of tumor specimen TCGA-77-A5G7-01B (aliquot TCGA-77-A5G7-01B-11D-A27K-08) from TCGA case TCGA-77-A5G7, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.2 years (23,090 days).
Specimen TCGA-77-A5G7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a6eff34-11b2-40e0-a153-c77983fde110.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5G7-10A (Blood Derived Normal), aliquot TCGA-77-A5G7-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48553710-6f9b-4116-8697-bab7c60f4d1d

The open-access MAF lists 105 somatic variants for this specimen: 70 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 30, Nonsense Mutation 4, RNA 3, Frame Shift Del 2, Intron 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3217C>T p.L1073F | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99687556; called by muse, mutect2, varscan2
- AKAP13 | c.5801A>G p.N1934S (on ENST00000394518 / NM_007200.5; = p.N1938S on NM_006738.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100774828; called by muse, mutect2, varscan2
- ANK2 | c.7223G>T p.G2408V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV100004600; called by muse, mutect2, varscan2
- BROX | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs939085791, COSV61799535, COSV61799878; called by muse, mutect2
- C5 | c.4993G>C p.D1665H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV99798946; called by muse, mutect2, varscan2
- CBLL2 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100081790; called by muse, mutect2, varscan2
- CGA | c.273+2T>G p.X91_splice | Splice Site (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100851754; called by muse, mutect2, varscan2
- CMTM5 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.691); catalogued as rs200320289, COSV100198226, COSV59304968; called by muse, mutect2, varscan2
- CMTR2 | c.1582G>C p.G528R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.154); catalogued as COSV100578949, COSV100579382; called by muse, mutect2, varscan2
- COL11A1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.899); catalogued as COSV100618223; called by muse, mutect2, varscan2
- CPNE3 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99548185; called by muse, mutect2, varscan2
- CREBZF | c.619A>T p.T207S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV99476504; called by muse, mutect2, varscan2
- CRYM | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs553362900, COSV99561970; called by muse, mutect2
- CXADR | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99515723; called by muse, mutect2, varscan2
- CYP1A1 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs778933231, COSV101122388; called by muse, mutect2, varscan2
- DBF4B | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV100154753; called by muse, mutect2, varscan2
- DOCK4 | c.2371C>A p.L791M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101448021; called by muse, mutect2, varscan2
- DPEP3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1419111203, COSV52051482; called by muse, mutect2, varscan2
- DSC1 | c.2444C>A p.A815E | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99938384; called by muse, mutect2, varscan2
- DST | c.16063A>G p.K5355E (on ENST00000361203 / NM_001374722.1; = p.K2943E on NM_015548.5) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs547846036, COSV99760674; called by muse, mutect2, varscan2
- EFCAB5 | c.1798A>T p.R600* | Nonsense Mutation (SNP) | VAF 62/254 reads (24%) | catalogued as COSV100300884; called by muse, mutect2, varscan2
- ERAP2 | c.1337T>C p.I446T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101163961; called by muse, mutect2, varscan2
- EVI2B | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as COSV100445696; called by muse, mutect2, varscan2
- F13B | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.464); catalogued as COSV100803517; called by muse, mutect2
- F13B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV100803518; called by muse, mutect2
- FAM111A | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs775891705, COSV100659490; called by muse, mutect2, varscan2
- FCN1 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100878985; called by muse, mutect2, varscan2
- GDF3 | c.543C>A p.F181L | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV100325076, COSV100325443; called by muse, mutect2
- GYS2 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.927); catalogued as COSV99680329; called by muse, mutect2, varscan2
- H4C12 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100694824, COSV100694826; called by muse, mutect2, varscan2
- H4C7 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99769309; called by muse, mutect2, varscan2
- HMX3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774114, COSV100774145; called by muse, mutect2, varscan2
- KLHDC7A | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV68771300; called by muse, mutect2, varscan2
- LRP1B | c.8066del p.C2689Ffs*8 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV67196430, COSV67242164; called by mutect2, pindel, varscan2
- LRRC66 | c.1795A>T p.R599W | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100603127; called by muse, mutect2
- LRRC66 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.753); catalogued as COSV100603128, COSV100603144; called by muse, mutect2
- LRRC7 | c.4499G>T p.S1500I (on ENST00000651989 / NM_001370785.2; = p.S1420I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50427750, COSV99230326; called by muse, mutect2
- LRRC73 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99447664; called by muse, varscan2
- MTCH1 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | catalogued as COSV101010231; called by muse, mutect2
- NCAM2 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV53057228, COSV99525718; called by muse, mutect2, varscan2
- NDN | c.400A>C p.K134Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV100086763; called by muse, mutect2, varscan2
- NDUFAF1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs200394888, COSV52975816; called by muse, mutect2
- NFKBIZ | c.1764T>A p.N588K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV100397277; called by muse, mutect2
- NNT | c.1177A>C p.T393P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99239715; called by muse, mutect2, varscan2
- OLFM3 | c.1297C>A p.P433T (on ENST00000338858 / NM_001288821.1; = p.P413T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58799558; called by muse, mutect2, varscan2
- OR14C36 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100507682; called by muse, mutect2, varscan2
- OR8H3 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100539168; called by muse, mutect2, varscan2
- OSCP1 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV99347604; called by muse, mutect2, varscan2
- PAPOLB | c.1402G>T p.V468F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101271641; called by muse, mutect2, varscan2
- PIGB | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99380771; called by muse, mutect2, varscan2
- PRDM2 | c.3650A>C p.K1217T | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99342872; called by muse, mutect2, varscan2
- PYGL | c.161T>G p.F54C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV99369175; called by muse, mutect2
- QPCT | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100621665; called by muse, mutect2
- RASGRP2 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1337075855, COSV100818374; called by muse, mutect2
- SCN2A | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99333878; called by muse, mutect2, varscan2
- SFMBT2 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739746; called by muse, mutect2, varscan2
- SI | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.147); catalogued as COSV100016480, COSV100017441; called by muse, mutect2
- SLC39A6 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309990; called by muse, mutect2, varscan2
- SPACA7 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs918762066, COSV99366936; called by muse, mutect2, varscan2
- TEK | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101193629; called by muse, mutect2, varscan2
- USP37 | c.2263A>G p.M755V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758424863, COSV99294942; called by muse, mutect2, varscan2
- VCAN | c.9799G>C p.V3267L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427589; called by muse, mutect2, varscan2
- XRN1 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs375372231; called by muse, mutect2
- ZEB1 | c.1800T>G p.Y600* | Nonsense Mutation (SNP) | VAF 39/114 reads (34%) | catalogued as COSV100315233; called by muse, mutect2, varscan2
- ZNF496 | c.43A>T p.S15C | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV99666292; called by muse, mutect2
- IGKV3D-11 | c.6A>T p.E2D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TNKS2 | c.286_290del p.H96Cfs*8 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- TP53 | c.632_643del p.T211_H214del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.403_405del p.E135del | In Frame Del (DEL) | VAF 31/220 reads (14%) | called by mutect2, pindel, varscan2
- ZNF142 | c.3967C>A p.Q1323K (on ENST00000411696 / NM_001379660.1; = p.Q1123K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.011); called by muse, mutect2
- ADGRB1 | c.3609G>A p.Q1203= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100030520; called by muse, mutect2
- AP3D1 | c.2040C>T p.P680= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs1417436728, COSV100643101; called by muse, mutect2, varscan2
- C1orf198 | c.201C>T p.D67= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1308458077, COSV100793516; called by muse, mutect2, varscan2
- CABIN1 | c.6525C>T p.A2175= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs756352023, COSV99574170; called by muse, mutect2, varscan2
- CALCRL | c.129A>T p.T43= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV101131049; called by muse, mutect2, varscan2
- CEMIP2 | c.1668C>T p.D556= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs200131462; called by muse, mutect2, varscan2
- COTL1 | c.315A>G p.V105= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99297225; called by muse, mutect2, varscan2
- CTCFL | c.1770C>A p.T590= | Silent (SNP) | VAF 77/201 reads (38%) | catalogued as COSV99713409; called by muse, mutect2, varscan2
- DDX5 | c.435A>G p.T145= | Silent (SNP) | VAF 74/223 reads (33%) | catalogued as COSV99858366; called by muse, mutect2, varscan2
- FER1L5 | c.4686T>C p.F1562= (on ENST00000623019; = p.F1535= on NM_001293083.2) | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1284741781, COSV101208923; called by muse, mutect2, varscan2
- GINS4 | c.468G>C p.V156= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99394621, COSV99394680; called by muse, mutect2, varscan2
- HIPK3 | c.384G>A p.K128= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV100306117; called by muse, mutect2, varscan2
- HPSE2 | c.1119A>G p.P373= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100986364; called by muse, mutect2
- KRT86 | c.945G>T p.L315= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV99525137; called by muse, varscan2
- LRP1B | c.2895A>G p.P965= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV101261924; called by muse, mutect2, varscan2
- MTMR2 | c.1227G>A p.G409= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100656882; called by muse, mutect2, varscan2
- PCDH15 | c.5154T>C p.P1718= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100228642; called by muse, mutect2, varscan2
- PDE6B | c.612A>G p.E204= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99728552; called by muse, mutect2, varscan2
- POU3F4 | c.789A>T p.T263= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100937356; called by muse, mutect2, varscan2
- RAB9B | c.42T>A p.G14= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV99686156; called by muse, mutect2, varscan2
- REG1B | c.246C>A p.A82= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100521545; called by muse, mutect2, varscan2
- ROS1 | c.6363C>T p.G2121= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs777221228, COSV100877792; called by muse, mutect2, varscan2
- SDK1 | c.5943G>A p.V1981= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as rs1398225998, COSV67391707; called by muse, mutect2
- SERPINB5 | c.276C>T p.L92= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV101237618; called by muse, mutect2, varscan2
- SERPING1 | c.162A>G p.L54= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99558218; called by muse, mutect2, varscan2
- SLC13A5 | c.276C>A p.G92= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs771703938, COSV99546251; called by muse, mutect2, varscan2
- TSPAN4 | c.171C>T p.L57= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs756260255, COSV100059564; called by muse, mutect2, varscan2
- TUBA3C | c.1134G>A p.L378= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV101313889; called by muse, mutect2, varscan2
- USP7 | c.2439A>G p.L813= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs148541392; called by muse, mutect2, varscan2
- ZNF566 | c.510C>T p.F170= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs767143946, COSV101091294; called by muse, mutect2, varscan2
- DIRC1 | n.278G>A | RNA (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100353016; called by muse, mutect2
- FAM74A3 | n.144G>T | RNA (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16954C>G | Intron (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- MDS2 | n.44A>G | RNA (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- PPFIBP1 | c.1633+471A>C | Intron (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99945583; called by muse, mutect2, varscan2
